Somatic mutation profile of tumor specimen TCGA-T2-A6WZ-01A (aliquot TCGA-T2-A6WZ-01A-21D-A34J-08) from TCGA case TCGA-T2-A6WZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G2; Age at diagnosis: 53.1 years (19,397 days).
Specimen TCGA-T2-A6WZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 213a1e6c-8503-4cd0-8a35-4d7ec8254e65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T2-A6WZ-10B (Blood Derived Normal), aliquot TCGA-T2-A6WZ-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4b336ec-7f04-4b2c-ab12-19170b1a76d5

The open-access MAF lists 97 somatic variants for this specimen: 71 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 59, Silent 26, Nonsense Mutation 6, Frame Shift Ins 3, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 34/52 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 19/69 reads (28%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACIN1 | c.2464A>G p.R822G | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99399227; called by muse, mutect2, varscan2
- ADAMTS9 | c.3189G>C p.E1063D | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV99898917; called by muse, mutect2, varscan2
- ALCAM | c.1442T>C p.V481A | Missense Mutation (SNP) | VAF 73/387 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV100064411; called by muse, mutect2, varscan2
- ANK2 | c.9682G>A p.V3228M | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs141013157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP27 | c.2357C>T p.S786L (on ENST00000428638 / NM_001282290.1; = p.S445L on NM_199282.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs1016002510, COSV100976466; called by muse, mutect2, varscan2
- ATCAY | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100008530; called by muse, mutect2, varscan2
- ATP6V0A1 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV99230605; called by muse, mutect2
- BIRC6 | c.5080A>T p.I1694F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.279); catalogued as COSV101427973; called by muse, mutect2, varscan2
- BRDT | c.1259T>G p.V420G | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV100746192; called by muse, mutect2, varscan2
- BTN3A1 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV99175655; called by muse, mutect2
- CACHD1 | c.3623A>G p.N1208S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV99261696; called by muse, mutect2, varscan2
- CLCN1 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.167); catalogued as COSV100577794; called by muse, mutect2, varscan2
- CNTN6 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372041513, COSV100610295; called by muse, mutect2, varscan2
- CYP11B2 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100010774; called by muse, mutect2, varscan2
- FAM161B | c.706C>T p.R236W (on ENST00000651776; = p.R173W on NM_152445.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs778270399, COSV99679622; called by muse, mutect2, varscan2
- GSE1 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs199942155, COSV53671014; called by muse, mutect2, varscan2
- GTSE1 | c.954A>T p.K318N | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101483193; called by muse, mutect2, varscan2
- HOOK2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404930236, COSV53402092, COSV99317376; called by muse, mutect2
- HSPE1-MOB4 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV99291397; called by muse, mutect2
- HTR5A | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV55280587, COSV99840025; called by muse, mutect2, varscan2
- IPP | c.183C>A p.Y61* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | catalogued as COSV100739419; called by muse, mutect2, varscan2
- IRX6 | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306254; called by muse, mutect2, varscan2
- IVD | c.302A>G p.Y101C (on ENST00000651168; = p.Y98C on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV99991411; called by muse, mutect2
- KCNK1 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs767247742, COSV64035053; called by muse, mutect2, varscan2
- KIAA1109 | c.2773G>T p.A925S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99147625; called by muse, mutect2, varscan2
- KLHDC8A | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as rs1000257355, COSV100903799; called by muse, mutect2, varscan2
- KLHL32 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV100987187; called by muse, mutect2
- LILRB4 | c.1008C>A p.N336K (on ENST00000391733 / NM_001278428.3; = p.N335K on NM_001278426.3) | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99553559; called by muse, mutect2, varscan2
- LRP1 | c.3425C>G p.S1142C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99674914; called by muse, mutect2, varscan2
- LRRC14 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752226395, COSV99467187; called by muse, mutect2, varscan2
- LRRC30 | c.650A>T p.E217V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV101274381; called by muse, mutect2, varscan2
- LRRTM3 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100791517; called by muse, mutect2, varscan2
- MLLT10 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100307599; called by muse, mutect2, varscan2
- MYBL2 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV53830892; called by muse, mutect2, varscan2
- NBAS | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99867902; called by muse, mutect2, varscan2
- NRG3 | c.1525G>C p.A509P | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100930902; called by muse, mutect2, varscan2
- OAS1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs779611860, COSV52534750; called by muse, mutect2, varscan2
- PAK3 | c.548C>G p.P183R (on ENST00000262836 / NM_001324328.2; = p.P168R on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV99456698; called by muse, mutect2, varscan2
- PAPPA2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1242233332, COSV100866603; called by muse, mutect2, varscan2
- PCBP1 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100340065; called by muse, mutect2, varscan2
- PPRC1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV53383804; called by muse, mutect2, varscan2
- PRCP | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100475731; called by muse, mutect2, varscan2
- RGL1 | c.776G>A p.C259Y (on ENST00000360851 / NM_001297672.2; = p.C294Y on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100486297; called by muse, mutect2, varscan2
- RTN3 | c.2842C>G p.L948V (on ENST00000377819 / NM_001265589.2; = p.L152V on NM_006054.4) | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100379956; called by muse, mutect2, varscan2
- SAP130 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as rs1029422515, COSV52093924; called by muse, mutect2, varscan2
- SDCCAG8 | c.295A>C p.M99L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100653969; called by muse, mutect2, varscan2
- SESTD1 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100090273; called by muse, mutect2, varscan2
- SLC35F5 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 29/410 reads (7%) | catalogued as COSV99829954; called by muse, mutect2
- SLCO6A1 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101134113, COSV101135170; called by muse, mutect2, varscan2
- SNRNP40 | c.955A>T p.I319L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV99745142; called by muse, mutect2, varscan2
- STK11IP | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV99822424; called by muse, mutect2, varscan2
- SUDS3 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | catalogued as rs1308781359, COSV100819990; called by muse, mutect2, varscan2
- TAP1 | c.1604C>G p.S535* | Nonsense Mutation (SNP) | VAF 6/104 reads (6%) | catalogued as COSV62755873; called by muse, mutect2
- TLL1 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50270448; called by muse, mutect2, varscan2
- TNFAIP6 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373227124; called by muse, mutect2, varscan2
- TRMT10C | c.1042A>T p.N348Y | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV99998252; called by muse, mutect2, varscan2
- TTN | c.43526C>G p.S14509* (on ENST00000591111; = p.S7085* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 19/327 reads (6%) | catalogued as COSV100599427; called by muse, mutect2
- TTN | c.43017C>G p.I14339M (on ENST00000591111; = p.I6915M on NM_003319.4) | Missense Mutation (SNP) | VAF 29/233 reads (12%) | PolyPhen possibly damaging (0.61); catalogued as COSV100599431; called by muse, mutect2, varscan2
- UBAC2 | c.964G>A p.D322N (on ENST00000403766 / NM_001144072.2; = p.D287N on NM_177967.4) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.627); catalogued as COSV100854150; called by muse, mutect2, varscan2
- UFSP2 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs180730337, COSV99248948; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746684956, COSV99691198; called by muse, mutect2, varscan2
- ZNF638 | c.2704G>C p.E902Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV100038207; called by muse, mutect2, varscan2
- ZNF713 | c.1157A>G p.K386R (on ENST00000633730 / NM_001366796.2; = p.K399R on NM_182633.3) | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV101448718; called by muse, mutect2, varscan2
- ZNF790 | c.1692C>G p.C564W | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100764781; called by muse, mutect2
- DDX1 | c.1292dup p.L431Ffs*23 | Frame Shift Ins (INS) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- IMMT | c.1749dup p.S584Ifs*11 | Frame Shift Ins (INS) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- RB1 | c.976_992del p.L326Rfs*9 | Frame Shift Del (DEL) | VAF 46/157 reads (29%) | called by mutect2, pindel, varscan2
- TOP1 | c.1759_1791del p.K587_T597del | In Frame Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel
- ZFP36L2 | c.387dup p.R130Sfs*344 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- APCDD1 | c.630G>A p.Q210= | Silent (SNP) | VAF 55/260 reads (21%) | catalogued as COSV100790030, COSV62372229; called by muse, mutect2, varscan2
- APPL2 | c.859A>C p.R287= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV99314509; called by muse, mutect2, varscan2
- CCDC170 | c.1803C>A p.L601= | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as COSV99498217; called by muse, mutect2, varscan2
- DMRTB1 | c.678C>T p.D226= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs769317497, COSV65112708; called by muse, mutect2, varscan2
- DNAI4 | c.303G>T p.L101= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV100925204; called by muse, mutect2, varscan2
- EOLA2 | c.288C>G p.P96= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV62207227, COSV62207229; called by muse, mutect2, varscan2
- FBXL5 | c.1632G>T p.A544= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV100377725; called by muse, mutect2, varscan2
- GRIN3A | c.690G>A p.R230= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs368705360; called by muse, mutect2, varscan2
- HTR5A | c.456C>A p.R152= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99839503; called by muse, mutect2, varscan2
- LAMA5 | c.2868C>G p.T956= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99438545; called by muse, mutect2
- MFAP4 | c.534C>G p.S178= | Silent (SNP) | VAF 10/163 reads (6%) | catalogued as COSV100218808; called by muse, mutect2
- MYO5A | c.4567C>T p.L1523= | Silent (SNP) | VAF 32/265 reads (12%) | catalogued as rs970006462, COSV100697403; called by muse, mutect2, varscan2
- PLEC | c.4305C>T p.S1435= (on ENST00000322810 / NM_201380.4; = p.S1325= on NM_000445.5) | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs1554706428, COSV100511907; called by muse, mutect2, varscan2
- RFPL1 | c.402C>G p.A134= | Silent (SNP) | VAF 19/255 reads (7%) | catalogued as COSV100585664; called by muse, mutect2
- SETX | c.1128A>G p.P376= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV99809036; called by muse, mutect2
- SHROOM4 | c.3189C>T p.I1063= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs781828818, COSV99173117; called by muse, mutect2, varscan2
- SI | c.4623C>G p.L1541= | Silent (SNP) | VAF 18/351 reads (5%) | catalogued as COSV100014417, COSV100016601, COSV52266243; called by muse, mutect2
- SUCO | c.702A>G p.A234= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99742216; called by muse, mutect2, varscan2
- SYNE1 | c.22968A>G p.S7656= (on ENST00000367255 / NM_182961.4; = p.S7585= on NM_033071.3) | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99556198; called by muse, mutect2, varscan2
- TM7SF2 | c.582G>C p.L194= | Silent (SNP) | VAF 97/325 reads (30%) | catalogued as COSV99659585; called by muse, mutect2, varscan2
- TMPRSS15 | c.1437T>C p.F479= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV99517188; called by muse, mutect2, varscan2
- UBASH3A | c.1416T>C p.G472= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV99369328; called by muse, mutect2, varscan2
- USH2A | c.12519G>C p.L4173= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV100230841, COSV56361121; called by muse, mutect2, varscan2
- WEE2 | c.1488C>G p.L496= | Silent (SNP) | VAF 82/251 reads (33%) | catalogued as COSV101187649; called by muse, mutect2, varscan2
- YKT6 | c.252A>G p.E84= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV99790509; called by muse, mutect2, varscan2
- ZNF800 | c.1377A>G p.K459= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV99757737; called by muse, mutect2, varscan2
